CCDI case PBCFGZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/69a4d5f7-1b68-4c3e-b4c1-3391f15ddc1c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,206 days).

Biospecimens (3 samples)
- Sample 0DQRZT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQS04: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQS0L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
